MMRF case MMRF_1838 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/27c2926f-2da2-4fe1-87b0-8d0b786a249c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 72 years; Vital status: Dead; Days to death: 1,005 days (2.8 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 72.7 years (26,537 days); ISS stage: I; Days to last known disease status: 1,005 days (2.8 years); Days to last follow up: 1,005 days (2.8 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 71 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 78 days; Days to treatment end: 155 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 209 days; Days to treatment end: 210 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 224 days; Days to treatment end: 224 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 316 days; Days to treatment end: 615 days (1.7 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 630 days (1.7 years); Days to treatment end: 639 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 630 days (1.7 years); Days to treatment end: 1,005 days (2.8 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,005.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 239 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.86 mg/dL; Immunoglobulin G 7.51 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.95 g/L; Beta 2 Microglobulin 2.07 µg/mL; Hemoglobin 7.87 mmol/L; Leukocytes 3.83 ×10⁹/L; Absolute Neutrophil 2.51 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.5 mmol/L; Albumin 44 g/L; Glucose 16.4 mmol/L.
- Day 99 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 90.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 3.89 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 2.72 ×10⁹/L; Absolute Neutrophil 2.24 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Glucose 11.6 mmol/L.
- Day 180 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 90.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL; Immunoglobulin G 3.61 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 2.91 µg/mL; Hemoglobin 6.7 mmol/L; Leukocytes 3.72 ×10⁹/L; Absolute Neutrophil 2.38 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Glucose 10.9 mmol/L.
- Day 259 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 27.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.24 mg/dL; Immunoglobulin G 2.68 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.51 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.71 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 5.6 g/dL; Glucose 8.2 mmol/L.
- Day 356 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 35.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Hemoglobin 6.45 mmol/L; Leukocytes 3.39 ×10⁹/L; Absolute Neutrophil 1.81 ×10⁹/L; Platelets 96 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 5.9 g/dL; Glucose 8.09 mmol/L.
- Day 454: Serum Free Immunoglobulin Light Chain, Kappa 51.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Hemoglobin 6.88 mmol/L; Leukocytes 1.73 ×10⁹/L; Absolute Neutrophil 0.7 ×10⁹/L; Platelets 71 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Glucose 6.38 mmol/L.
- Day 526: Serum Free Immunoglobulin Light Chain, Kappa 55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.71 mg/dL; Hemoglobin 6.82 mmol/L; Leukocytes 3.26 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 91 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 6.4 g/dL; Glucose 7.59 mmol/L.
- Day 615 (ECOG 1): Hemoglobin 7.56 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 79 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 7.87 mmol/L.
- Day 686 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 38.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.32 mg/dL; Immunoglobulin G 3.27 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.87 ×10⁹/L; Absolute Neutrophil 3.91 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.45 mmol/L; Albumin 36 g/L; Total Protein 5.6 g/dL; Glucose 6.44 mmol/L.
- Day 797 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 30 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.31 mg/dL; Immunoglobulin G 3.19 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 3.05 ×10⁹/L; Absolute Neutrophil 2.21 ×10⁹/L; Platelets 92 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 5.7 g/dL; Glucose 6.55 mmol/L.
- Day 882 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 33.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 4.72 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.71 ×10⁹/L; Absolute Neutrophil 2.48 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.58 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 9.41 mmol/L.

Other clinical attributes
- Day -6: Weight: 130 kg; Height: 180 cm.

Family history
- Relative with cancer history: yes; Relationship type: Child.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lymphoma.

Biospecimens (4 samples)
- Sample MMRF_1838_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1838_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
- Sample MMRF_1838_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 99 days.
- Sample MMRF_1838_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 180 days.
